Somatic mutation profile of tumor specimen TCGA-QR-A70U-01A (aliquot TCGA-QR-A70U-01A-11D-A35D-08) from TCGA case TCGA-QR-A70U, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 46.7 years (17,062 days).
Specimen TCGA-QR-A70U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f705fda-7c2b-43c1-9225-4a36c0f43ece.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70U-10A (Blood Derived Normal), aliquot TCGA-QR-A70U-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/903c32de-27f4-4480-9342-77b03f1e1fea

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRD1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs775441478, COSV53457780; called by muse, varscan2
- CASP3 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.327); catalogued as rs1363258170; called by muse, mutect2
- CHD3 | c.2897G>A p.R966Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555611692; ClinVar: uncertain significance; called by muse, mutect2
- DOCK4 | c.2620G>T p.E874* | Nonsense Mutation (SNP) | VAF 16/164 reads (10%) | catalogued as COSV70239534; called by muse, mutect2
- GBA | c.709A>C p.K237Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.308); catalogued as CM020712; called by muse, mutect2, varscan2
- ROBO2 | c.1821T>G p.S607R | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59909731; called by muse, mutect2, varscan2
- CACNA1H | c.4339T>A p.L1447M | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SDR42E1 | c.884A>G p.E295G | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.349); called by muse, mutect2
- USP9X | c.1812_1815del p.Q605Ffs*7 | Frame Shift Del (DEL) | VAF 48/175 reads (27%) | called by pindel, varscan2
- ZNF106 | c.5453_5460del p.H1818Lfs*20 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by pindel, varscan2
- ZNF35 | c.116A>T p.H39L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2
- NAF1 | c.1410A>G p.P470= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs752138200, COSV56803656; called by muse, mutect2, varscan2
- PDE7A | c.1179A>G p.K393= (on ENST00000401827 / NM_001242318.3; = p.K367= on NM_002603.4) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1448402881; called by muse, mutect2, varscan2
- SCUBE2 | c.1986T>C p.H662= | Silent (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- SGSM1 | c.1971C>T p.T657= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1451919703, COSV101240412; called by muse, mutect2
